CCDI case PBCFLY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/e0ae0710-bddb-4f47-8639-24faedef675f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor with rhabdomyoblastic differentiation: ICD-O-3 morphology code: 9561/3; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.5 years (1,652 days).

Biospecimens (3 samples)
- Sample 0DRKK9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRKKI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRKKR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
